Somatic mutation profile of tumor specimen C3N-00379-01 (aliquot CPT0015520009) from CPTAC case C3N-00379, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 41.8 years (15,271 days).
Specimen C3N-00379-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57006ea1-af51-4038-af06-7e6cf863d42d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00379-71 (Blood Derived Normal), aliquot CPT0015740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5568e7a3-5e18-4326-8f4f-2f67e8c0631b

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, Splice Region 2, Intron 2, 5'Flank 2, Nonsense Mutation 2, RNA 2, Splice Site 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 42/295 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 38/248 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 6/44 reads (14%) | hotspot (GDC flag); called by pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 52/418 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>C p.R130P | Missense Mutation (SNP) | VAF 103/415 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3091C>T p.R1031* | Nonsense Mutation (SNP) | VAF 23/168 reads (14%) | catalogued as rs1309067397, COSV59389278; called by muse, mutect2, varscan2
- ADGRE3 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs146538980, COSV99506456; called by muse, mutect2, varscan2
- DCAF4L2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 16/339 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs865992251, COSV60477474, COSV60477956; called by muse, mutect2
- H1-3 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1362151560, COSV99768829; called by muse, mutect2, varscan2
- HHATL | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs144753590; called by muse, mutect2, varscan2
- IGF2BP2 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs759787490; called by muse, mutect2
- MYO5A | c.2257G>A p.G753S | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs776415086; called by muse, mutect2
- MYRF | c.533C>T p.P178L (on ENST00000278836 / NM_001127392.3; = p.P169L on NM_013279.4) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1310547158; called by muse, varscan2
- PGAP4 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs375705359; called by muse, mutect2, varscan2
- PTPRQ | c.6263C>T p.S2088L (on ENST00000616559; = p.S2055L on NM_001145026.2) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768307387, COSV57033921; called by mutect2, varscan2
- RBPMS | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV55122267; called by mutect2, varscan2
- RNF146 | c.973C>T p.R325* (on ENST00000368314 / NM_001242850.2; = p.R324* on NM_030963.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/128 reads (12%) | catalogued as COSV58931388; called by muse, mutect2, varscan2
- SYNJ1 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as rs749980859; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13C | c.11111A>G p.N3704S (on ENST00000644861 / NM_020821.3; = p.N3661S on NM_017684.5) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs1201414326; called by muse, mutect2, varscan2
- ANKRD30B | c.2214A>C p.L738F | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.266); called by muse, mutect2
- ASCC3 | c.4894G>C p.E1632Q | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CABYR | c.864G>T p.M288I | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- COL14A1 | c.4028C>T p.T1343I | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DARS2 | c.1563+6G>C | Splice Region (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- DENND5A | c.911G>T p.C304F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- FNIP2 | c.1823G>A p.R608K | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2
- MCIDAS | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.4803C>G p.H1601Q | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- OCRL | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2
- PSD | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMC6 | c.788C>G p.A263G (on ENST00000612399; = p.A249G on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.046); called by muse, mutect2
- PTGER4 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2
- SDK2 | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAAR2 | c.568G>A p.G190S (on ENST00000367931 / NM_001033080.1; = p.G145S on NM_014626.3) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- TAF1L | c.3473C>A p.A1158E | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- TRAM1 | c.123G>A p.E41= | Splice Region (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- TTC21A | c.558+1G>C p.X186_splice | Splice Site (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- CD36 | c.1041G>A p.L347= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as rs1463671275; called by muse, mutect2
- GALNT12 | c.795C>T p.F265= | Silent (SNP) | VAF 57/345 reads (17%) | catalogued as rs774616588, COSV66662288; called by muse, mutect2, varscan2
- GRM3 | c.837C>T p.D279= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV100862885, COSV64467042; called by muse, mutect2
- KCNH3 | c.1980C>T p.A660= | Silent (SNP) | VAF 32/238 reads (13%) | catalogued as rs374816936; called by muse, mutect2, varscan2
- PANX3 | c.663C>T p.S221= | Silent (SNP) | VAF 17/239 reads (7%) | catalogued as rs377074068; called by muse, mutect2
- STRA6 | c.1758C>G p.S586= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- TSR1 | c.816G>A p.L272= | Silent (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- FAM182B | n.632C>A | RNA (SNP) | VAF 32/225 reads (14%) | called by muse, varscan2
- FOXI2 | chr10:127736446 G>A | 5'Flank (SNP) | VAF 3/25 reads (12%) | catalogued as rs1348938959; called by muse, mutect2
- MMAB | c.*1262_*1265dup | 3'UTR (INS) | VAF 18/136 reads (13%) | called by mutect2, pindel
- SSPOP | n.5727C>T | RNA (SNP) | VAF 12/95 reads (13%) | catalogued as rs562038201, COSV100022664; called by muse, mutect2, varscan2
- TSPYL4 | chr6:116258838 A>G | 5'Flank (SNP) | VAF 52/351 reads (15%) | called by muse, mutect2, varscan2
- TTLL3 | c.1155-20G>T | Intron (SNP) | VAF 54/320 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.10361-5510C>A | Intron (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
